Somatic mutation profile of tumor specimen 0DKSZC from CCDI case PBBYSP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,386 days).
Specimen 0DKSZC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 87432d90-1a08-4595-b1c1-5b45912daf8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKSTV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9adfc8ed-d763-4ff6-8fcc-f20fd1375a99

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'Flank 1, Nonsense Mutation 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GBA3 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 60/992 reads (6%) | catalogued as rs201515557, COSV72437804, COSV72438258; called by muse, mutect2
- TXNDC16 | c.791C>T p.T264I | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2
- TCHHL1 | chr1:152080329 G>A | 3'Flank (SNP) | VAF 300/971 reads (31%) | catalogued as rs987115451; called by muse, mutect2, varscan2
